Somatic mutation profile of tumor specimen TCGA-32-1977-01A (aliquot TCGA-32-1977-01A-01D-1353-08) from TCGA case TCGA-32-1977, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.5 years (23,205 days).
Specimen TCGA-32-1977-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8923fe02-13ea-4999-b3a9-a78aa1ef2b56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-1977-10C (Blood Derived Normal), aliquot TCGA-32-1977-10C-01D-1353-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4de58545-568a-4f9b-ae77-c9a5b9bc6161

The open-access MAF lists 75 somatic variants for this specimen: 54 protein-altering or splice-affecting, 21 silent.
By variant classification: Missense Mutation 44, Silent 21, Frame Shift Del 3, Splice Region 2, Nonsense Mutation 2, Frame Shift Ins 1, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1C | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs754527953, COSV54643569; called by muse, mutect2, varscan2
- ARID2 | c.4043A>T p.D1348V | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.261); catalogued as rs1429729468, COSV57609255; called by muse, mutect2, varscan2
- BPGM | c.346A>T p.R116* | Nonsense Mutation (SNP) | VAF 31/120 reads (26%) | catalogued as COSV61325207; called by muse, mutect2, varscan2
- C15orf39 | c.2995G>A p.G999S | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.541); catalogued as COSV62297342; called by muse, mutect2, varscan2
- CBX2 | c.1414G>A p.D472N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs199672117, COSV53969578; called by muse, mutect2, varscan2
- COL10A1 | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.022); catalogued as rs555747394, COSV54573676; called by muse, mutect2, varscan2
- CRHR2 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs776448334, COSV59266461; called by muse, mutect2, varscan2
- DECR2 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as rs370736528; called by muse, mutect2, varscan2
- DNMBP | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs138795130, COSV60634393; called by muse, mutect2, varscan2
- E2F6 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 65/332 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV56216206; called by muse, mutect2, varscan2
- FAP | c.887T>A p.L296H | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV51864539; called by muse, mutect2, varscan2
- GDF3 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as COSV61713079; called by muse, mutect2, varscan2
- GPR132 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.242); catalogued as rs774535285, COSV61678160; called by muse, mutect2, varscan2
- HELZ | c.3464T>C p.I1155T | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.628); catalogued as rs373787062; called by muse, mutect2, varscan2
- IL17RB | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1466608887, COSV55473624; called by muse, mutect2, varscan2
- KIAA0825 | c.209A>C p.D70A | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56955704; called by muse, mutect2, varscan2
- KIF2B | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 16/78 reads (21%) | catalogued as rs543871191, COSV52128303; called by muse, mutect2, varscan2
- KRT78 | c.384G>A p.K128= | Splice Region (SNP) | VAF 10/70 reads (14%) | catalogued as COSV58852570; called by muse, mutect2, varscan2
- LRP2 | c.2455C>T p.R819C | Missense Mutation (SNP) | VAF 22/407 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749942746, COSV55543681; called by muse, mutect2
- LRRC37A3 | c.4202T>G p.V1401G | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV58536027; called by muse, mutect2, varscan2
- LRRC8E | c.240G>T p.Q80H | Missense Mutation (SNP) | VAF 57/303 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV60718673; called by muse, mutect2, varscan2
- LZTR1 | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758338373, COSV53145247, COSV53147916; called by muse, mutect2, varscan2
- MAP4K3 | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747296551, COSV55715268; called by muse, mutect2, varscan2
- MARCHF10 | c.24G>T p.R8S | Missense Mutation (SNP) | VAF 57/253 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100248125, COSV60889015; called by muse, mutect2, varscan2
- MARCHF4 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.828); catalogued as rs1164420325, COSV56105152; called by muse, mutect2, varscan2
- MCM6 | c.255-1G>C p.X85_splice | Splice Site (SNP) | VAF 77/276 reads (28%) | catalogued as COSV51467729; called by muse, mutect2, varscan2
- NAAA | c.999C>T p.N333= | Splice Region (SNP) | VAF 44/221 reads (20%) | catalogued as rs775392768, COSV54433044; called by muse, mutect2, varscan2
- NLRP12 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 46/370 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs760185291, COSV60747502; called by muse, mutect2, varscan2
- OTOL1 | c.1299G>C p.L433F | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60007634; called by muse, mutect2, varscan2
- OXA1L | c.664G>A p.G222S (on ENST00000285848; = p.G162S on NM_005015.5) | Missense Mutation (SNP) | VAF 460/2566 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as COSV53536445; called by mutect2, varscan2
- PLA2G4F | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 16/217 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750820840, COSV51828057; called by muse, mutect2
- PLD4 | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV66915487; called by muse, mutect2, varscan2
- PLEKHN1 | c.1625C>T p.T542M (on ENST00000379409; = p.T490M on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs72631892, COSV58022733; called by muse, mutect2, varscan2
- PTEN | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as CM004280, CM124222, COSV100909550, COSV64289957, COSV64297290; called by muse, mutect2, varscan2
- PTPRG | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs764140516, COSV55650697, COSV55660767; called by muse, mutect2
- RIMS3 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs149583022; called by muse, mutect2, varscan2
- SHROOM3 | c.2128C>A p.P710T | Missense Mutation (SNP) | VAF 87/313 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.307); catalogued as COSV56034135; called by muse, varscan2
- SLC27A6 | c.1253A>G p.K418R | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV52485096; called by muse, mutect2, varscan2
- SLC8B1 | c.116A>T p.Q39L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV52529267; called by mutect2, varscan2
- TBX15 | c.1010T>C p.M337T (on ENST00000369429 / NM_001330677.2; = p.M231T on NM_152380.3) | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as rs760132433, COSV52873440; called by muse, mutect2, varscan2
- TBX5 | c.514A>T p.I172F | Missense Mutation (SNP) | VAF 86/374 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59863091; called by muse, mutect2, varscan2
- TDRD9 | c.2584G>A p.V862I | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs201957950, COSV59150725; called by muse, mutect2, varscan2
- TEX55 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs138666071; called by muse, mutect2, varscan2
- TLN2 | c.4966A>C p.K1656Q | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); catalogued as COSV60892036; called by muse, mutect2, varscan2
- TMEM266 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.023); catalogued as rs1185061892, COSV66380288; called by muse, mutect2, varscan2
- TP63 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV53196522, COSV53212854; called by muse, mutect2, varscan2
- UEVLD | c.465G>C p.L155F | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV55578942; called by muse, mutect2, varscan2
- ZNF528 | c.604A>C p.T202P | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.4); catalogued as COSV64620275; called by muse, mutect2, varscan2
- ZNF76 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV57354650; called by muse, mutect2, varscan2
- CCDC102B | c.205_207dup p.I69dup | In Frame Ins (INS) | VAF 52/290 reads (18%) | called by mutect2, pindel, varscan2
- PCDH7 | c.2461del p.V821* | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | called by pindel, varscan2
- PHF1 | c.1191del p.E398Sfs*96 (on ENST00000374516 / NM_024165.3; = p.R394Efs*58 on NM_002636.5) | Frame Shift Del (DEL) | VAF 16/75 reads (21%) | called by mutect2, pindel, varscan2
- TAOK3 | c.985del p.E329Kfs*9 | Frame Shift Del (DEL) | VAF 24/123 reads (20%) | called by mutect2, pindel, varscan2
- ZRANB2 | c.901dup p.R301Kfs*34 (on ENST00000370920 / NM_203350.3; = p.R301Kfs*15 on NM_005455.5) | Frame Shift Ins (INS) | VAF 26/158 reads (16%) | called by mutect2, varscan2
- DNAH3 | c.5142C>T p.G1714= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as rs143127393; called by muse, mutect2, varscan2
- DPYSL2 | c.1479G>A p.G493= | Silent (SNP) | VAF 111/496 reads (22%) | catalogued as COSV60784399; called by muse, mutect2, varscan2
- FGFRL1 | c.1422C>T p.L474= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV53258333; called by muse, mutect2, varscan2
- FLG | c.4278C>T p.S1426= | Silent (SNP) | VAF 91/418 reads (22%) | catalogued as rs375923587; called by muse, mutect2, varscan2
- FOXG1 | c.837C>T p.T279= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as rs570340475, COSV57398042; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2403C>T p.I801= (on ENST00000265755 / NM_016328.3; = p.I786= on NM_005685.4) | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as rs1449327416, COSV56088871; called by muse, mutect2, varscan2
- IGFALS | c.894C>T p.S298= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs759846527, COSV51906803; called by muse, mutect2
- ITGAD | c.2397C>T p.N799= | Silent (SNP) | VAF 68/299 reads (23%) | catalogued as rs1303308761, COSV66757763, COSV66758857; called by muse, mutect2, varscan2
- LYSMD3 | c.6A>G p.A2= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as COSV60057652, COSV60058139; called by muse, mutect2
- OR2T2 | c.579G>A p.T193= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs564223502, COSV100737773; called by mutect2, varscan2
- PTPRF | c.2727G>A p.R909= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV63446680; called by muse, mutect2, varscan2
- SLC18A3 | c.1263C>T p.Y421= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs1316371552, COSV60319703; called by muse, mutect2, varscan2
- SLC2A6 | c.1278C>T p.P426= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs782516532, COSV52470885; called by muse, mutect2
- SV2A | c.117C>T p.D39= | Silent (SNP) | VAF 56/234 reads (24%) | catalogued as rs368036992; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYTL5 | c.1026C>T p.S342= | Silent (SNP) | VAF 53/128 reads (41%) | catalogued as COSV52902990; called by muse, mutect2, varscan2
- TMPO | c.915C>T p.V305= | Silent (SNP) | VAF 38/153 reads (25%) | catalogued as rs889989804, COSV99702168; called by muse, mutect2, varscan2
- TRPM2 | c.552G>A p.P184= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as COSV55972885; called by muse, mutect2, varscan2
- TTLL3 | c.2442C>T p.V814= | Silent (SNP) | VAF 38/162 reads (23%) | catalogued as rs756601012; called by mutect2, varscan2
- UCHL3 | c.75A>T p.L25= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV66460032; called by muse, mutect2, varscan2
- UGT2B28 | c.1479G>T p.V493= | Silent (SNP) | VAF 36/205 reads (18%) | catalogued as rs775380271, COSV59431535, COSV59433158; called by muse, mutect2, varscan2
- WLS | c.1389C>T p.G463= | Silent (SNP) | VAF 19/148 reads (13%) | catalogued as rs537667082, COSV52037330; called by muse, mutect2, varscan2
